Surgical pathology report (de-identified scan), TCGA case TCGA-IR-A3LC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IR-A3LC-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: SP: Uterus, cervix, parametria with partial vagina
- 2: SP: Left common iliac lymph nodes
- 3: SP: Left external iliac lymph nodes (
- 4: SP: Left hypogastric lymph nodes (
- 5: SP: Left obturator lymph node
- 6: SP: Right common iliac lymph node
- 7: SP: Right external iliac lymph nodes
- 8: SP: Right obturator lymph node)
- 9: SP: Right hypogastric lymph node

DIAGNOSIS:

- 1) UTERUS, PARAMETRIA, CERVIX; RADICAL HYSTERECTOMY:
- INVASIVE SQUAMOUS CELL CARCINOMA OF UTERINE CERVIX, POORLY DIFFERENTIATED.
- THE TUMOR IS 2.5 CM IN GREATEST DIMENSION.
- THE MAXIMAL THICKNESS OF THE CERVICAL STROMAL INVASION IS 1.7 CM.
- THE THICKNESS OF THE CERVIX IN THE AREA OF MAXIMAL TUMOR INVASION IS 1.9 CM.
- NO EVIDENCE OF TUMOR MULTICENTRICITY IS IDENTIFIED.
- NO IN SITU CARCINOMA IS IDENTIFIED.
- VASCULAR INVASION IS PRESENT.
- NO VAGINAL EXTENSION IS IDENTIFIED.
- THE TUMOR EXTENDS INTO THE LOWER UTERINE SEGMENT (STROMA ONLY), FOCALLY ON THE POSTERIOR ASPECT.
- NO PARAMETRIAL INVOLVEMENT IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE ENDOMETRIUM IS BENIGN PROLIFERATIVE.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: LEIOMYOMA, 1.0 CM IN GREATEST DIMENSION.
- ONE BENIGN LEFT PARAMETRIAL LYMPH NODE IDENTIFIED (0/1).
- 2) LYMPH NODES, LEFT COMMON ILIAC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 3) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:

** Continued on next page **

PATH
REPORT

100-0-3

carcinoma, squamous cell 8070/3

Site: cervix, NOS C53.9

hw
12/20/11

[page 2 of 2]
TSS Name/#

- FOUR BENIGN LYMPH NODES (0/4).

4) LYMPH NODES, LEFT HYPOGASTRIC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).

5) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- ELEVEN BENIGN LYMPH NODES (0/11).

6) LYMPH NODES, RIGHT COMMON ILIAC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

7) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- FIFTEEN BENIGN LYMPH NODES (0/15).

8) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- SEVEN BENIGN LYMPH NODES (0/7).

9) LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Source: NCI Genomic Data Commons file e257adbb-f4ea-476a-8290-9e7c20d6d385 (TCGA-IR-A3LC.97FF892D-6CAD-4376-BB48-082EC5BC4C39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).